Somatic mutation profile of tumor specimen 0331bd9b-94a5-4d02-ae43-6288e9 (aliquot 0331bd9b-94a5-4d02-ae43-6288e9_D6) from CPTAC case 26OV013, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 0331bd9b-94a5-4d02-ae43-6288e9: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70f375f5-c1ba-4144-8f5a-21e284753934.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 6b420957-5153-4dbb-8d5d-ea4add (Blood Derived Normal), aliquot 6b420957-5153-4dbb-8d5d-ea4add_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/934e7c12-0d1f-4e23-acbb-56b7f187d18d

The open-access MAF lists 64 somatic variants for this specimen: 40 protein-altering or splice-affecting, 17 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 17, Intron 6, Nonsense Mutation 2, 5'Flank 1, Frame Shift Ins 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 197/267 reads (74%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BVES | c.959A>G p.H320R | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750996567; called by muse, mutect2, varscan2
- CRYBG3 | c.6010G>A p.E2004K | Missense Mutation (SNP) | VAF 49/351 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs529146889; called by muse, mutect2, varscan2
- DCSTAMP | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1250850322, COSV52576068; called by muse, mutect2, varscan2
- IGF2BP1 | c.1550C>T p.T517M | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1567828704; called by muse, mutect2, varscan2
- ITGA9 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 167/452 reads (37%) | catalogued as rs371914464; called by muse, mutect2, varscan2
- MAP2 | c.2650C>T p.Q884* | Nonsense Mutation (SNP) | VAF 143/407 reads (35%) | catalogued as COSV52307654; called by muse, mutect2, varscan2
- MAP3K6 | c.2768G>A p.R923Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1292023678, COSV58870415; called by muse, mutect2, varscan2
- MRGPRX2 | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 57/375 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs747335673, COSV61674032; called by muse, mutect2, varscan2
- MYH1 | c.3388C>T p.R1130W | Missense Mutation (SNP) | VAF 132/189 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56844359; called by muse, mutect2, varscan2
- NPTX1 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 45/370 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776629293; called by muse, mutect2, varscan2
- NXPH3 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 220/529 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as rs1394800262; called by muse, mutect2, varscan2
- OR10G7 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 50/399 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs150421981; called by muse, mutect2, varscan2
- SLC11A1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs774135476; called by muse, varscan2
- SLC12A5 | c.3211C>T p.R1071W (on ENST00000454036 / NM_001134771.2; = p.R1048W on NM_020708.5) | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs369042030, CM1511611; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SQSTM1 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 225/749 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs201239306, CM155582, COSV52974069; ClinVar: uncertain significance; called by muse, varscan2
- ZFR2 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs756610328; called by muse, mutect2, varscan2
- ABCC12 | c.680A>G p.D227G | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY1 | c.1460G>A p.G487D | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CARD11 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- DENND4A | c.3558G>T p.E1186D | Missense Mutation (SNP) | VAF 106/290 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EMILIN2 | c.1696G>A p.G566S | Missense Mutation (SNP) | VAF 109/255 reads (43%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EYS | c.7798C>T p.P2600S | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- FIG4 | c.2564dup p.S856Lfs*4 | Frame Shift Ins (INS) | VAF 173/353 reads (49%) | called by mutect2, pindel, varscan2
- IL23A | c.123C>G p.C41W | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- KANSL3 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 94/416 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM5A | c.1441del p.C481Afs*37 | Frame Shift Del (DEL) | VAF 55/188 reads (29%) | called by mutect2, pindel, varscan2
- KLC2 | c.1240C>T p.H414Y | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- LIPE | c.3010G>T p.A1004S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- MZF1 | c.1135A>G p.T379A | Missense Mutation (SNP) | VAF 76/305 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- NUP155 | c.2220A>C p.K740N (on ENST00000231498 / NM_153485.3; = p.K681N on NM_004298.4) | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLB1 | c.2032C>G p.Q678E | Missense Mutation (SNP) | VAF 36/388 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2
- RBM48 | c.1017+8_1017+17del | Splice Region (DEL) | VAF 33/111 reads (30%) | called by mutect2, pindel, varscan2
- RGPD4 | c.4693G>T p.A1565S | Missense Mutation (SNP) | VAF 183/552 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SPRY2 | c.158A>G p.N53S | Missense Mutation (SNP) | VAF 118/598 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SVEP1 | c.5759G>T p.G1920V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- TKT | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM151A | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRIP10 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRPM8 | c.2659G>C p.G887R | Missense Mutation (SNP) | VAF 120/388 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCNB1 | c.1251G>A p.Q417= | Silent (SNP) | VAF 61/147 reads (41%) | called by muse, mutect2, varscan2
- DLGAP2 | c.1938C>T p.R646= | Silent (SNP) | VAF 50/95 reads (53%) | catalogued as rs759975717, COSV101423146; called by muse, mutect2, varscan2
- EYS | c.7797C>T p.H2599= | Silent (SNP) | VAF 33/121 reads (27%) | called by muse, mutect2, varscan2
- IGLV4-3 | c.312C>T p.D104= | Silent (SNP) | VAF 208/534 reads (39%) | catalogued as rs371756657; called by muse, mutect2, varscan2
- KMT2D | c.4377C>T p.P1459= | Silent (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- OR8H2 | c.54G>C p.L18= | Silent (SNP) | VAF 20/166 reads (12%) | catalogued as COSV100542353; called by muse, mutect2, varscan2
- OTOG | c.6216C>T p.R2072= | Silent (SNP) | VAF 118/384 reads (31%) | catalogued as rs1008270692; called by muse, mutect2, varscan2
- PPARD | c.636G>A p.V212= | Silent (SNP) | VAF 115/359 reads (32%) | called by muse, mutect2, varscan2
- RBMXL3 | c.936C>T p.G312= | Silent (SNP) | VAF 33/112 reads (29%) | catalogued as rs782770623, COSV100407533; called by muse, mutect2, varscan2
- RPL27A | c.63C>A p.R21= | Silent (SNP) | VAF 52/162 reads (32%) | called by muse, mutect2, varscan2
- SCX | c.312C>T p.T104= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs1443818145; called by muse, mutect2, varscan2
- SETD2 | c.7356G>A p.S2452= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs368025625; called by muse, mutect2, varscan2
- SIPA1L3 | c.4311C>G p.L1437= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as rs540654899; called by muse, varscan2
- SLC15A3 | c.1560C>T p.P520= | Silent (SNP) | VAF 28/169 reads (17%) | catalogued as rs756444074, COSV99137837; called by muse, mutect2, varscan2
- SORCS2 | c.714C>T p.G238= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as rs567595853, COSV61164050; called by muse, mutect2, varscan2
- VSTM2B | c.405C>T p.D135= | Silent (SNP) | VAF 20/600 reads (3%) | catalogued as COSV59260584; called by muse, mutect2
- VWF | c.7707G>A p.A2569= | Silent (SNP) | VAF 42/204 reads (21%) | catalogued as rs143235468; called by muse, mutect2, varscan2
- AL355916.3 | c.419+22847G>A | Intron (SNP) | VAF 55/126 reads (44%) | called by muse, mutect2, varscan2
- NADK | c.264-1859C>T | Intron (SNP) | VAF 36/91 reads (40%) | catalogued as rs527839189; called by muse, mutect2, varscan2
- PROC | c.401-41C>A | Intron (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- RAP1GAP | c.1429-915G>A | Intron (SNP) | VAF 58/145 reads (40%) | catalogued as rs764594114; called by muse, mutect2, varscan2
- RNF168 | c.681-23A>G | Intron (SNP) | VAF 30/353 reads (8%) | called by muse, mutect2
- SP5 | chr2:170713742 G>C | 5'Flank (SNP) | VAF 38/207 reads (18%) | called by muse, mutect2, varscan2
- ZEB1 | c.58+43538C>T | Intron (SNP) | VAF 116/227 reads (51%) | catalogued as rs866305300; called by muse, mutect2, varscan2
